CCDI case PBBVRY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified male genital organs.
https://portal.gdc.cancer.gov/cases/8e088404-e64a-4bdc-8d44-ee57bdd2f56c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Epididymis; Age at diagnosis: 20.8 years (7,612 days).

Biospecimens (3 samples)
- Sample 0DIMVU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWP: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMX2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
